TARGET case TARGET-00-NAAEPE — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/2d7b7a68-5520-47b3-bcc3-f08e7e4b92f5

Biospecimens (1 sample)
- Sample TARGET-00-NAAEPE-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
